Somatic mutation profile of tumor specimen TCGA-DK-A6B6-01A (aliquot TCGA-DK-A6B6-01A-11D-A30E-08) from TCGA case TCGA-DK-A6B6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 57.5 years (21,007 days).
Specimen TCGA-DK-A6B6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ccca5b7-efe2-4479-a97d-ef1de9f13d5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A6B6-10A (Blood Derived Normal), aliquot TCGA-DK-A6B6-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/84e9825c-6367-415a-a86d-077789b7d224

The open-access MAF lists 1,122 somatic variants for this specimen: 735 protein-altering or splice-affecting, 356 silent, 31 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 625, Silent 356, Nonsense Mutation 84, Intron 16, Frame Shift Del 10, Splice Site 7, RNA 6, Splice Region 5, 5'UTR 3, 5'Flank 3, 3'UTR 2, Translation Start Site 2.

Variants (750 of 1,122; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 94/302 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519816, COSV54062198, COSV54062802; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SESN2 | c.1273A>G p.I425V | Missense Mutation (SNP) | VAF 28/100 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.18); PolyPhen benign (0.247); catalogued as rs371133353; called by muse, mutect2, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 33/55 reads (60%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- AAR2 | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV57925132; called by muse, mutect2, varscan2
- ABCB5 | c.2621G>A p.G874E (on ENST00000404938 / NM_001163941.2; = p.G429E on NM_178559.6) | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1165165839, COSV99329723; called by muse, mutect2
- AC004922.1 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 78/121 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as COSV53559648; called by muse, mutect2, varscan2
- ACCS | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.781); catalogued as COSV55460650; called by muse, mutect2, varscan2
- ACER3 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV53603601; called by muse, mutect2, varscan2
- ACKR4 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99391791; called by muse, mutect2, varscan2
- ACOX1 | c.1381C>T p.Q461* | Nonsense Mutation (SNP) | VAF 36/94 reads (38%) | catalogued as COSV99503418; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3028G>A p.E1010K | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV54473327; called by muse, mutect2, varscan2
- ADGRV1 | c.11245G>A p.D3749N | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); catalogued as COSV67996773; called by muse, mutect2, varscan2
- ADSL | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53410956; called by muse, mutect2, varscan2
- AFF1 | c.1627G>C p.E543Q | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.724); catalogued as COSV57125336; called by muse, mutect2, varscan2
- AFF3 | c.3016G>A p.E1006K | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57877597; called by muse, mutect2, varscan2
- AGO3 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as COSV55797846; called by muse, mutect2, varscan2
- AHNAK | c.12879C>G p.I4293M | Missense Mutation (SNP) | VAF 110/256 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV57228544; called by muse, mutect2, varscan2
- AIG1 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV51635442; called by muse, mutect2, varscan2
- AK7 | c.1909G>C p.E637Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.062); catalogued as COSV50870058, COSV50884648; called by muse, mutect2, varscan2
- AKAP10 | c.1609C>T p.H537Y | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs146622968; called by muse, mutect2, varscan2
- AKAP10 | c.703C>T p.H235Y | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV56733496; called by muse, mutect2, varscan2
- AKNA | c.286G>C p.E96Q | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV56315360; called by muse, mutect2, varscan2
- AL645922.1 | c.1353G>C p.E451D | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.631); catalogued as COSV54962952; called by muse, mutect2, varscan2
- AL645922.1 | c.3541C>G p.R1181G | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64888667; called by muse, mutect2, varscan2
- ALG10B | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs1442690265, COSV58144963; called by muse, mutect2, varscan2
- ALKBH1 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53175099, COSV53175118; called by muse, mutect2, varscan2
- ALMS1 | c.5444C>T p.S1815F | Missense Mutation (SNP) | VAF 94/215 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.106); catalogued as rs528863432, COSV52517109; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALOX15 | c.1410C>G p.I470M | Missense Mutation (SNP) | VAF 41/62 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV53401296; called by muse, mutect2, varscan2
- ANGPTL2 | c.1165G>C p.E389Q | Missense Mutation (SNP) | VAF 11/374 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52234618; called by muse, mutect2
- ANK1 | c.1829C>T p.A610V | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV55898315; called by muse, mutect2, varscan2
- ANK2 | c.3343G>C p.D1115H | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52193234; called by muse, mutect2, varscan2
- ANKLE2 | c.1460C>T p.S487F | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61707689; called by muse, mutect2, varscan2
- ANKRD55 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.014); catalogued as rs1561244893, COSV61951417; called by muse, mutect2, varscan2
- ANKS6 | c.1382G>C p.R461P | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62050205, COSV62052560; called by muse, mutect2, varscan2
- ANP32A | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.254); catalogued as COSV51190025; called by muse, varscan2
- ANXA5 | c.934C>G p.L312V | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56640408; called by muse, mutect2, varscan2
- ARF6 | c.78G>C p.K26N | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53598568; called by muse, varscan2
- ARFGAP2 | c.1071G>C p.K357N | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV60302654; called by muse, mutect2, varscan2
- ARHGAP31 | c.1633G>C p.E545Q | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.782); catalogued as COSV51800316; called by muse, mutect2, varscan2
- ARHGAP32 | c.2128C>T p.L710F (on ENST00000310343 / NM_001378025.1; = p.L361F on NM_014715.4) | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV59856801; called by muse, mutect2, varscan2
- ARMT1 | c.349G>C p.E117Q | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66179207; called by muse, mutect2, varscan2
- ARNTL | c.1618-1G>A p.X540_splice (on ENST00000403290 / NM_001297719.2; = p.X539_splice on NM_001178.5 and 4 other RefSeq transcripts) | Splice Site (SNP) | VAF 9/39 reads (23%) | catalogued as COSV99533470; called by muse, mutect2
- ARRDC3 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV54366826; called by muse, mutect2, varscan2
- ARVCF | c.2747C>G p.S916C | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.264); catalogued as COSV52891190; called by muse, varscan2
- ASXL3 | c.3272G>C p.G1091A | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.012); catalogued as COSV52482193; called by muse, mutect2, varscan2
- ATAD5 | c.1449G>T p.K483N | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV58974986, COSV58979982; called by muse, mutect2, varscan2
- ATF7IP2 | c.754G>C p.D252H | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.06); catalogued as COSV61095697; called by muse, mutect2, varscan2
- ATG16L2 | c.1224G>T p.K408N | Missense Mutation (SNP) | VAF 39/70 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV58363259; called by muse, mutect2, varscan2
- ATP13A1 | c.2768C>T p.S923F | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV52284807; called by muse, mutect2, varscan2
- ATP5F1A | c.1039C>T p.R347W | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56362136; called by muse, mutect2, varscan2
- ATP6V0D2 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs1163346793, COSV53415511; called by muse, mutect2, varscan2
- ATP8B4 | c.1086G>C p.K362N | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.028); catalogued as COSV52726066; called by muse, mutect2, varscan2
- ATR | c.5778G>C p.Q1926H | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV63386318; called by muse, mutect2, varscan2
- AVPI1 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs553651349, COSV65698041; called by muse, mutect2, varscan2
- B2M | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV62562840, COSV62562870, COSV62563658; called by muse, mutect2, varscan2
- B4GALT3 | c.880G>C p.D294H | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV60528343; called by muse, mutect2, varscan2
- BAG1 | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV65652011; called by muse, mutect2, varscan2
- BAG6 | c.1432C>T p.H478Y | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.983); catalogued as COSV99276687; called by muse, mutect2
- BARD1 | c.1556C>G p.S519C | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53618418; called by muse, mutect2, varscan2
- BBOF1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67455773; called by muse, mutect2, varscan2
- BNIP5 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as COSV71325271, COSV71325897; called by muse, mutect2, varscan2
- BRD4 | c.2740G>A p.E914K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as rs1192169871, COSV54596262; called by muse, mutect2, varscan2
- BRD8 | c.1121C>T p.S374L (on ENST00000254900 / NM_139199.2; = p.S447L on NM_006696.4) | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); catalogued as COSV50174487; called by muse, mutect2, varscan2
- BRMS1 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 45/110 reads (41%) | catalogued as rs1565206314, COSV100240216, COSV60820714; called by muse, mutect2, varscan2
- BRWD1 | c.6880G>A p.E2294K | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as COSV59001598; called by muse, mutect2, varscan2
- BRWD1 | c.1239C>G p.I413M | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV60903887; called by muse, mutect2, varscan2
- BTF3 | c.370C>T p.Q124* (on ENST00000380591 / NM_001037637.1; = p.Q80* on NM_001207.4) | Nonsense Mutation (SNP) | VAF 48/112 reads (43%) | catalogued as rs1182433703, COSV100246660; called by muse, mutect2, varscan2
- C1QTNF3 | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 16/29 reads (55%) | catalogued as COSV99180695; called by muse, mutect2, varscan2
- C1orf174 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64365682, COSV64365966; called by muse, mutect2, varscan2
- C1orf52 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 71/168 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV54000033; called by muse, mutect2, varscan2
- C5orf38 | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 61/161 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV100121673, COSV57412756, COSV57414154; called by muse, mutect2, varscan2
- C7orf26 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as rs746262056, COSV60420809; called by muse, mutect2, varscan2
- C7orf26 | c.1085C>G p.S362* | Nonsense Mutation (SNP) | VAF 25/47 reads (53%) | catalogued as COSV100732858; called by muse, mutect2, varscan2
- CACNA1H | c.2455G>A p.E819K | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs375165169; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAMK1 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.171); catalogued as COSV56540682; called by muse, mutect2, varscan2
- CAPN10 | c.423G>C p.Q141H | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as COSV54380380; called by muse, mutect2, varscan2
- CASP8 | c.717C>G p.I239M (on ENST00000432109 / NM_033355.3; = p.I256M on NM_001228.4) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as COSV51860909; called by muse, mutect2, varscan2
- CAST | c.1118C>T p.S373L (on ENST00000341926; = p.S456L on NM_001750.7 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV57790282; called by muse, mutect2, varscan2
- CC2D1A | c.2053G>C p.D685H | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58786676; called by muse, mutect2, varscan2
- CC2D1A | c.2190G>C p.Q730H | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58786683; called by muse, mutect2, varscan2
- CCDC7 | c.4157G>C p.*1386Sext*? | Nonstop Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV100177903; called by muse, mutect2, varscan2
- CCDC9B | c.1475C>T p.S492F | Missense Mutation (SNP) | VAF 99/189 reads (52%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.568); catalogued as COSV66876419; called by muse, mutect2, varscan2
- CCPG1 | c.2043C>G p.I681M | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV51244410; called by muse, mutect2, varscan2
- CDC42BPB | c.2254G>C p.E752Q | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.175); catalogued as COSV63477231; called by muse, mutect2, varscan2
- CDH6 | c.2236G>A p.V746M | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); catalogued as rs538483207, COSV54064383; called by muse, mutect2, varscan2
- CDK1 | c.254T>C p.M85T | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as COSV57350567; called by muse, mutect2, varscan2
- CDK12 | c.4130C>T p.S1377L (on ENST00000447079 / NM_016507.4; = p.S1368L on NM_015083.3) | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV71003178; called by muse, mutect2, varscan2
- CDK9 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.183); catalogued as rs371317161; called by muse, mutect2, varscan2
- CDKN2A | c.159G>T p.M53I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as CM056552, CM950229, COSV58683319, COSV58703741, COSV58710848; called by muse, mutect2, varscan2
- CDKN2A | c.123_130del p.N42Rfs*75 | Frame Shift Del (DEL) | VAF 58/206 reads (28%) | catalogued as COSV58719398; called by mutect2, pindel, varscan2
- CENPB | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1257221408, COSV60150592; called by muse, varscan2
- CEP120 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs767371755, COSV60269116; called by muse, mutect2, varscan2
- CEP126 | c.1939C>T p.H647Y | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.23); PolyPhen benign (0.085); catalogued as COSV54831797; called by muse, mutect2, varscan2
- CEP126 | c.2992G>A p.E998K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.523); catalogued as COSV54831810; called by muse, mutect2, varscan2
- CERT1 | c.953C>G p.S318C (on ENST00000405807 / NM_001130105.1; = p.S190C on NM_005713.3) | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV54665621; called by muse, mutect2
- CFAP94 | c.1946G>C p.R649T (on ENST00000320267 / NM_001352064.2; = p.R655T on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100209123; called by muse, mutect2
- CGB1 | c.180C>A p.T60= | Splice Region (SNP) | VAF 20/148 reads (14%) | catalogued as COSV100031577; called by muse, mutect2
- CGB1 | c.179C>A p.T60N | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.326); catalogued as COSV100031578; called by muse, mutect2
- CHAF1A | c.686G>A p.G229E | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.031); catalogued as COSV56677021; called by muse, mutect2, varscan2
- CILK1 | c.1229G>A p.R410K (on ENST00000350082 / NM_001375397.1; = p.R403K on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.345); catalogued as COSV63156343; called by muse, mutect2, varscan2
- CILP2 | c.2110G>A p.G704S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV52281227; called by muse, mutect2, varscan2
- CILP2 | c.2608G>A p.D870N | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs866044723, COSV52281237; called by muse, mutect2, varscan2
- CILP2 | c.2744G>A p.R915Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1568370580, COSV52281249; called by muse, mutect2, varscan2
- CITED2 | c.438G>A p.M146I | Missense Mutation (SNP) | VAF 72/171 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs866907470, COSV62726997; called by muse, mutect2, varscan2
- CITED2 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.972); catalogued as COSV62727002; called by muse, mutect2, varscan2
- CLEC16A | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as rs74163613, COSV68501694; called by muse, mutect2, varscan2
- CLEC4C | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 46/112 reads (41%) | catalogued as COSV100665404; called by muse, mutect2, varscan2
- CLSTN3 | c.2660C>T p.S887F | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.332); catalogued as COSV56941041; called by muse, mutect2, varscan2
- CNOT1 | c.6608C>T p.S2203F | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55323172; called by muse, mutect2, varscan2
- CNOT1 | c.1924C>T p.Q642* | Nonsense Mutation (SNP) | VAF 20/98 reads (20%) | catalogued as COSV100408851, COSV57775507; called by muse, mutect2, varscan2
- CNOT2 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.205); catalogued as COSV57507628; called by muse, mutect2, varscan2
- CNTROB | c.2567G>A p.G856D | Missense Mutation (SNP) | VAF 48/77 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as COSV66609667; called by muse, mutect2, varscan2
- COG2 | c.1534C>T p.Q512* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV100794642; called by muse, mutect2, varscan2
- COL18A1 | c.5119G>T p.E1707* (on ENST00000359759 / NM_130444.3; = p.E1472* on NM_030582.4) | Nonsense Mutation (SNP) | VAF 21/31 reads (68%) | catalogued as COSV100229228; called by muse, mutect2, varscan2
- COL22A1 | c.4691C>T p.P1564L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as COSV57364499; called by muse, mutect2, varscan2
- COMT | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 20/68 reads (29%) | catalogued as COSV99258488; called by muse, mutect2, varscan2
- COPZ2 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.266); catalogued as COSV50058421, COSV99133599; called by muse, mutect2
- COQ10B | c.554C>G p.S185C | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99827305; called by muse, mutect2
- CORO2A | c.1065G>A p.M355I | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV59665256; called by muse, mutect2, varscan2
- CORO6 | c.710G>A p.G237D | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61472207, COSV61472552; called by muse, mutect2, varscan2
- COX7B2 | c.147C>G p.F49L | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57224153; called by muse, mutect2, varscan2
- CPSF1 | c.2689C>T p.H897Y | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV58235920; called by muse, mutect2, varscan2
- CPSF4 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as COSV99461645; called by muse, mutect2
- CRABP2 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as rs866002426, COSV63959032, COSV63959081; called by muse, mutect2, varscan2
- CRTC3 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 107/562 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51601322; called by muse, mutect2, varscan2
- CRYBA4 | c.244G>A p.G82S | Missense Mutation (SNP) | VAF 35/252 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.834); catalogued as rs376710882; called by muse, mutect2, varscan2
- CTNNA2 | c.41C>A p.P14H | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63568809; called by muse, mutect2, varscan2
- CTNND1 | c.2300C>T p.S767F (on ENST00000399050 / NM_001085458.2; = p.S761F on NM_001331.3) | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as COSV62386630; called by muse, mutect2, varscan2
- CXCR6 | c.944C>A p.S315* | Nonsense Mutation (SNP) | VAF 40/90 reads (44%) | catalogued as COSV99945404; called by muse, mutect2, varscan2
- CXXC1 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV53277521; called by muse, mutect2, varscan2
- CYP19A1 | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as COSV53062773; called by muse, mutect2, varscan2
- DAZAP1 | c.985C>T p.Q329* | Nonsense Mutation (SNP) | VAF 69/189 reads (37%) | catalogued as COSV51837043; called by muse, mutect2, varscan2
- DBF4 | c.867G>C p.E289D | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.317); catalogued as rs1166557686, COSV55999376; called by muse, mutect2, varscan2
- DBF4 | c.1142C>G p.S381C | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV55995904, COSV55999384; called by muse, mutect2, varscan2
- DBR1 | c.1265C>T p.S422F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV53431430; called by muse, mutect2, varscan2
- DCAF12 | c.1325C>T p.S442L | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.548); catalogued as COSV63514153; called by muse, mutect2, varscan2
- DCAF16 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV66384407; called by muse, mutect2, varscan2
- DCC | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as rs1420293884, COSV59142160; called by muse, mutect2, varscan2
- DCTN1 | c.79C>A p.L27M | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.392); catalogued as COSV62621685; called by muse, mutect2, varscan2
- DENND4B | c.2281G>C p.E761Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63408400, COSV63412395; called by muse, mutect2, varscan2
- DGKA | c.1080G>C p.L360F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs772027345, COSV59384265; called by muse, mutect2, varscan2
- DGKH | c.1694C>T p.S565F | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV54943510; called by muse, mutect2, varscan2
- DIP2C | c.3938C>T p.P1313L | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55182245; called by muse, mutect2, varscan2
- DIS3 | c.2703C>A p.F901L | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as COSV66708270; called by muse, mutect2, varscan2
- DIS3L | c.1378G>C p.E460Q (on ENST00000319212 / NM_001143688.3; = p.E377Q on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV59912680; called by muse, mutect2, varscan2
- DLG5 | c.182T>A p.L61* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as COSV100967355; called by muse, mutect2, varscan2
- DMTF1 | c.1957G>C p.E653Q | Missense Mutation (SNP) | VAF 53/102 reads (52%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.624); catalogued as COSV57539469; called by muse, mutect2, varscan2
- DMXL1 | c.2747C>G p.S916C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.884); catalogued as COSV60722603; called by muse, mutect2, varscan2
- DMXL1 | c.3367G>C p.D1123H | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.176); catalogued as rs757195330, COSV60722623; called by muse, mutect2, varscan2
- DNAH10 | c.6339C>A p.F2113L (on ENST00000409039; = p.F2052L on NM_207437.3) | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68996529, COSV69004066; called by muse, mutect2, varscan2
- DNAH6 | c.2221C>T p.Q741* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV52877400; called by muse, mutect2
- DNAH8 | c.11845C>G p.R3949G | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59485585; called by muse, mutect2, varscan2
- DNAH9 | c.2165C>T p.A722V | Missense Mutation (SNP) | VAF 87/132 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs780659225, COSV52362172, COSV52380924; called by muse, mutect2, varscan2
- DNTTIP1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 89/226 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV101009986, COSV65460739; called by muse, mutect2, varscan2
- DOCK1 | c.613C>G p.Q205E | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.85); PolyPhen benign (0.041); catalogued as COSV54760269; called by muse, mutect2, varscan2
- DOK1 | c.736G>C p.E246Q | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV51207488, COSV51216457, COSV99284105; called by muse, mutect2, varscan2
- DOK2 | c.1018C>T p.R340* | Nonsense Mutation (SNP) | VAF 44/119 reads (37%) | catalogued as rs757494381, COSV99374639; called by muse, mutect2, varscan2
- DPP8 | c.2129G>A p.R710Q (on ENST00000341861 / NM_001320875.2; = p.R694Q on NM_130434.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55684136; called by muse, mutect2, varscan2
- DSG1 | c.2799G>A p.M933I | Missense Mutation (SNP) | VAF 99/306 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV57139718; called by muse, mutect2, varscan2
- DTL | c.1188G>C p.E396D | Missense Mutation (SNP) | VAF 81/159 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV65342609; called by muse, mutect2, varscan2
- DTWD1 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 29/199 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as COSV52072416; called by muse, mutect2, varscan2
- DTX2 | c.1054C>T p.L352F | Missense Mutation (SNP) | VAF 20/241 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV56865779; called by muse, mutect2
- DUSP2 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1361161328, COSV56620698; called by muse, mutect2, varscan2
- DVL1 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs966017949, COSV66680731; called by muse, mutect2, varscan2
- DYNC1H1 | c.11021C>T p.S3674L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs757529671, COSV64143873; called by muse, mutect2, varscan2
- DYNC1I2 | c.713C>G p.S238C | Missense Mutation (SNP) | VAF 15/19 reads (79%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV99783749; called by muse, mutect2, varscan2
- EDEM3 | c.2369C>G p.S790C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.789); catalogued as COSV58921274, COSV58928843; called by muse, mutect2, varscan2
- EFHC1 | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.19); catalogued as COSV64138054; called by muse, mutect2, varscan2
- EHMT1 | c.1555C>T p.L519F | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58382975; called by muse, mutect2, varscan2
- EHMT2 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as rs754527146, COSV100977154, COSV64998055; called by muse, mutect2, varscan2
- EIF2S1 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV56453582; called by muse, mutect2, varscan2
- EIF3D | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV53405757; called by muse, mutect2
- EIF4A2 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56218961; called by muse, mutect2, varscan2
- EIF5 | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 24/69 reads (35%) | catalogued as COSV53685647, COSV99384707; called by muse, mutect2, varscan2
- ELMO3 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs372924076, COSV62605629, COSV62606231; called by muse, mutect2, varscan2
- ELP2 | c.1906C>T p.R636* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as rs368507377; called by muse, mutect2, varscan2
- EML5 | c.5629G>A p.D1877N (on ENST00000380664; = p.D1885N on NM_183387.3) | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51774397; called by muse, mutect2, varscan2
- EML5 | c.3028C>G p.L1010V | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.969); catalogued as COSV61352615; called by muse, mutect2, varscan2
- ENDOU | c.909C>G p.I303M (on ENST00000422538 / NM_001172439.2; = p.I262M on NM_006025.4) | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV57466326; called by muse, mutect2, varscan2
- EP400 | c.2720C>G p.S907C | Missense Mutation (SNP) | VAF 96/228 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); catalogued as COSV57788721; called by muse, mutect2, varscan2
- EPB41L4A | c.1540C>T p.Q514* | Nonsense Mutation (SNP) | VAF 19/66 reads (29%) | catalogued as COSV99813069; called by muse, mutect2, varscan2
- EPHA5 | c.2897C>A p.A966D | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.403); catalogued as rs750694433, COSV99897631; called by mutect2, varscan2
- EPS8 | c.1399C>T p.Q467* | Nonsense Mutation (SNP) | VAF 36/105 reads (34%) | catalogued as COSV99842870; called by muse, mutect2, varscan2
- ERBB3 | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 44/186 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as COSV57264899; called by muse, mutect2, varscan2
- ERBIN | c.91C>T p.H31Y | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs924011788, COSV52328888; called by muse, mutect2, varscan2
- EVI2B | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 59/220 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV58365286; called by muse, varscan2
- EVI2B | c.209C>G p.S70* | Nonsense Mutation (SNP) | VAF 54/220 reads (25%) | catalogued as COSV100445434, COSV58364385; called by muse, varscan2
- FAH | c.632G>C p.R211T | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs1039905839, COSV55724032; called by muse, mutect2, varscan2
- FAM111A | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs1210745166, COSV64656038; called by muse, mutect2, varscan2
- FAM117A | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53634339; called by muse, mutect2, varscan2
- FAM149A | c.1876C>T p.P626S (on ENST00000356371 / NM_001367768.2; = p.P335S on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as COSV57030819; called by muse, mutect2, varscan2
- FAM193A | c.2266C>T p.P756S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.167); catalogued as COSV61199608; called by muse, mutect2, varscan2
- FAM47B | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 49/79 reads (62%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs1181134835, COSV100264635, COSV61457176; called by muse, mutect2, varscan2
- FAM83H | c.2717C>T p.S906L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV62030691; called by muse, mutect2, varscan2
- FAM98C | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 138/492 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762721238, COSV53040019; called by muse, mutect2, varscan2
- FASN | c.4888C>T p.P1630S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs746519327, COSV60762256; called by muse, mutect2, varscan2
- FAT1 | c.12088C>T p.P4030S | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV71671654; called by muse, mutect2, varscan2
- FAT1 | c.11120C>G p.S3707* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as COSV71672121; called by muse, mutect2, varscan2
- FAT1 | c.7694C>T p.S2565L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.079); catalogued as rs1390713115, COSV71676275; called by muse, mutect2, varscan2
- FBXW8 | c.966G>C p.L322F (on ENST00000309909; = p.L360F on NM_012174.1) | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0.018); catalogued as COSV59297155, COSV59304104; called by muse, mutect2, varscan2
- FCHO1 | c.2367G>C p.Q789H | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV53185987; called by muse, mutect2, varscan2
- FCRL3 | c.1339G>A p.G447R | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63841631; called by muse, mutect2, varscan2
- FEM1B | c.319C>G p.L107V | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60989918; called by muse, mutect2, varscan2
- FEM1B | c.1194G>C p.L398F | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV60989928; called by muse, mutect2, varscan2
- FGD5 | c.2502G>C p.Q834H | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.838); catalogued as COSV99547704; called by muse, mutect2, varscan2
- FGFRL1 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.351); catalogued as rs200852436, COSV99294897; called by muse, mutect2, varscan2
- FLNB | c.5837C>T p.S1946F | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55898844; called by muse, mutect2, varscan2
- FNBP1 | c.865C>G p.Q289E | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV63091447; called by muse, mutect2, varscan2
- FRMD6 | c.428C>T p.S143F (on ENST00000344768 / NM_001267046.2; = p.S135F on NM_152330.4) | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV61091286; called by muse, mutect2, varscan2
- FRRS1 | c.1422-1G>A p.X474_splice | Splice Site (SNP) | VAF 37/101 reads (37%) | catalogued as COSV54924883; called by muse, mutect2, varscan2
- FURIN | c.2077C>T p.R693W | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as rs754366900, COSV51574462; called by muse, mutect2, varscan2
- FUS | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 63/173 reads (36%) | catalogued as COSV99568462; called by muse, mutect2, varscan2
- FUT2 | c.820G>C p.D274H | Missense Mutation (SNP) | VAF 70/238 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67179865; called by muse, mutect2, varscan2
- FYCO1 | c.2371C>T p.Q791* | Nonsense Mutation (SNP) | VAF 28/78 reads (36%) | catalogued as COSV99945409; called by muse, mutect2, varscan2
- FZD10 | c.535G>C p.E179Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV57476297; called by muse, mutect2, varscan2
- GABRE | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 70/107 reads (65%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV64821764; called by muse, mutect2, varscan2
- GALNT10 | c.1373C>A p.A458E | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.971); catalogued as COSV51735521, COSV99770245; called by muse, mutect2
- GAPVD1 | c.3079C>T p.Q1027* (on ENST00000394104; = p.Q1054* on NM_015635.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 24/50 reads (48%) | catalogued as COSV99782925; called by muse, mutect2, varscan2
- GARNL3 | c.2390C>T p.S797L | Missense Mutation (SNP) | VAF 53/185 reads (29%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.636); catalogued as rs1283371831, COSV59231360; called by muse, mutect2, varscan2
- GCAT | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50649837; called by muse, mutect2, varscan2
- GCN1 | c.5533C>T p.H1845Y | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as COSV56115802; called by muse, mutect2, varscan2
- GEMIN2 | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as COSV51627749, COSV51629976; called by muse, mutect2, varscan2
- GFM2 | c.2155C>T p.Q719* | Nonsense Mutation (SNP) | VAF 31/83 reads (37%) | catalogued as COSV54667686; called by muse, mutect2, varscan2
- GGA2 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59170848; called by muse, mutect2, varscan2
- GGCX | c.1723G>C p.E575Q | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.379); catalogued as COSV52090799; called by muse, varscan2
- GGCX | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.835); catalogued as rs947143910, COSV52090806; called by muse, varscan2
- GGH | c.49G>C p.G17R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.344); catalogued as COSV52652382; called by muse, mutect2, varscan2
- GGT6 | c.893C>T p.A298V (on ENST00000574154 / NM_001122890.3; = p.A266V on NM_153338.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.991); catalogued as COSV54605383; called by muse, mutect2, varscan2
- GGT6 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 55/87 reads (63%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV54605393; called by muse, mutect2, varscan2
- GLIS3 | c.1823G>A p.G608E | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.652); catalogued as COSV60937369; called by muse, mutect2, varscan2
- GLUD1 | c.1401C>T p.L467= | Splice Region (SNP) | VAF 47/106 reads (44%) | catalogued as COSV53281704; called by muse, mutect2, varscan2
- GNAI2 | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 116/293 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.264); catalogued as COSV56496072; called by muse, mutect2, varscan2
- GNAT2 | c.957C>G p.I319M | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV63555463; called by muse, mutect2, varscan2
- GNAT2 | c.582G>C p.L194F | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV63555475; called by muse, mutect2, varscan2
- GNL2 | c.1993G>C p.E665Q | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.694); catalogued as COSV56171739, COSV99953480; called by muse, mutect2, varscan2
- GOLGA2 | c.844G>A p.D282N | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV70168977; called by muse, mutect2, varscan2
- GPATCH8 | c.2839C>T p.R947W | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs941326216, COSV59199524; called by muse, mutect2, varscan2
- GPIHBP1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as CM162017, COSV58209289; called by muse, mutect2, varscan2
- GPNMB | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV51701579; called by muse, mutect2, varscan2
- GPR141 | c.291C>G p.I97M | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV57734357; called by muse, mutect2, varscan2
- GPR37L1 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1442641947, COSV66162898; called by muse, mutect2, varscan2
- GPRC5B | c.191G>C p.G64A | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.996); catalogued as COSV56029042; called by muse, mutect2, varscan2
- GTF2F2 | c.404C>G p.S135C | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV61243341; called by muse, mutect2, varscan2
- GUF1 | c.1969G>C p.D657H | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV54948832; called by muse, mutect2, varscan2
- H1-10 | c.461C>T p.S154F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as rs765023771, COSV100412921, COSV100412961; called by muse, mutect2
- H2BC4 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.812); catalogued as rs879122516, COSV58414927, COSV58416609, COSV58417570; called by muse, mutect2, varscan2
- HAND1 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as COSV50563580, COSV50563644; called by muse, mutect2, varscan2
- HAUS6 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV65840961; called by muse, mutect2, varscan2
- HELZ | c.3502C>G p.L1168V | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.081); catalogued as COSV100699112, COSV62381342; called by muse, mutect2, varscan2
- HERC1 | c.9631G>C p.E3211Q | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV71250762; called by muse, mutect2, varscan2
- HERC1 | c.5093G>T p.G1698V | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.642); catalogued as COSV71250766; called by muse, mutect2, varscan2
- HHAT | c.678C>G p.I226M | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.424); catalogued as COSV54803596; called by muse, mutect2, varscan2
- HIVEP2 | c.4771G>A p.D1591N | Missense Mutation (SNP) | VAF 52/169 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.164); catalogued as COSV50084614; called by muse, mutect2, varscan2
- HIVEP2 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV50084924; called by muse, mutect2, varscan2
- HLX | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs751088009, COSV65045195, COSV65045833; called by muse, mutect2, varscan2
- HMGCR | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as COSV99843134; called by muse, mutect2, varscan2
- HNRNPD | c.790C>G p.Q264E | Missense Mutation (SNP) | VAF 99/262 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.584); catalogued as COSV58315071; called by muse, mutect2, varscan2
- HNRNPK | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV61091358; called by muse, mutect2, varscan2
- HOMER3 | c.15-1G>A p.X5_splice | Splice Site (SNP) | VAF 4/16 reads (25%) | catalogued as COSV55359126; called by muse, mutect2, varscan2
- HOXA2 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 34/62 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749965554, COSV56068042; called by muse, mutect2, varscan2
- HOXB2 | c.838C>T p.R280C | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV57488484; called by muse, mutect2, varscan2
- HOXB5 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as COSV53314463; called by muse, mutect2, varscan2
- HOXB7 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV53311738, COSV99494155; called by muse, mutect2, varscan2
- HPR | c.65C>G p.S22* | Nonsense Mutation (SNP) | VAF 15/101 reads (15%) | catalogued as COSV99930846; called by muse, mutect2, varscan2
- HSD11B2 | c.730G>T p.D244Y | Missense Mutation (SNP) | VAF 86/223 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as CM981000, COSV52098446, COSV52100214; called by muse, mutect2, varscan2
- HSD17B2 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV52278951; called by muse, mutect2, varscan2
- HSP90AB1 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 31/123 reads (25%) | catalogued as rs765906022, COSV62334504, COSV62336891; called by muse, mutect2, varscan2
- HSP90AB1 | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV62336521; called by muse, mutect2, varscan2
- HYDIN | c.15244G>A p.E5082K | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV66642870; called by muse, mutect2, varscan2
- IAH1 | c.91C>T p.Q31* | Nonsense Mutation (SNP) | VAF 12/33 reads (36%) | catalogued as COSV99432644; called by muse, mutect2, varscan2
- IARS1 | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355300511, COSV65113916, COSV65117476; called by muse, mutect2, varscan2
- ICA1 | c.1397C>T p.S466L | Missense Mutation (SNP) | VAF 60/117 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55583986, COSV55585281; called by muse, mutect2, varscan2
- ID1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65888610, COSV65888972; called by muse, mutect2, varscan2
- IGIP | c.21G>C p.M7I | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV60963944, COSV60964748; called by muse, mutect2, varscan2
- IKBIP | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.711); catalogued as COSV54491447; called by muse, mutect2, varscan2
- IL17RB | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55474729; called by muse, mutect2, varscan2
- INHBE | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as rs571755879, COSV56989335; called by muse, mutect2, varscan2
- INKA2 | c.25G>A p.D9N | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs756832621, COSV61879207; called by muse, mutect2, varscan2
- INTS2 | c.817C>T p.H273Y | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV52157259; called by muse, mutect2, varscan2
- IPO11 | c.1894C>T p.Q632* | Nonsense Mutation (SNP) | VAF 27/76 reads (36%) | catalogued as COSV100320472; called by muse, mutect2, varscan2
- IPO5 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.228); catalogued as rs780861333, COSV55160505; called by muse, mutect2, varscan2
- IPO7 | c.448C>T p.L150F | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV65685200; called by muse, mutect2, varscan2
- IQGAP1 | c.1506G>A p.M502I | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV51592268; called by muse, mutect2, varscan2
- ISY1-RAB43 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.023); catalogued as rs1286073653, COSV100167509; called by muse, varscan2
- ITGB2 | c.2224C>T p.L742F (on ENST00000302347; = p.L718F on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV56614850; called by muse, mutect2, varscan2
- ITGB6 | c.151C>T p.H51Y | Missense Mutation (SNP) | VAF 81/127 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1014857218, COSV51796102; called by muse, mutect2, varscan2
- IZUMO2 | c.640C>G p.Q214E | Missense Mutation (SNP) | VAF 90/400 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV53231598; called by muse, mutect2, varscan2
- JADE1 | c.104C>G p.S35C | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV56909921; called by muse, mutect2, varscan2
- JMJD1C | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as rs544541157, COSV67868375; called by muse, mutect2, varscan2
- JTB | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV55132889; called by muse, mutect2, varscan2
- KBTBD6 | c.1136C>T p.T379I | Missense Mutation (SNP) | VAF 75/116 reads (65%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.462); catalogued as COSV65272130; called by muse, mutect2, varscan2
- KCND3 | c.1876G>C p.E626Q | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV56180280, COSV56191155; called by muse, mutect2, varscan2
- KCNF1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.052); catalogued as rs773536391, COSV54462309, COSV54464047; called by muse, mutect2, varscan2
- KHDRBS1 | c.1220C>T p.S407F | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV56983050; called by muse, mutect2, varscan2
- KIAA0753 | c.1369C>T p.L457F | Missense Mutation (SNP) | VAF 84/125 reads (67%) | SIFT tolerated (0.65); PolyPhen benign (0.063); catalogued as rs776028596, COSV63819152; called by muse, mutect2
- KIAA1522 | c.193C>T p.Q65* (on ENST00000373480 / NM_001198972.2; = p.Q124* on NM_020888.3) | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | catalogued as COSV53865456; called by muse, mutect2, varscan2
- KIDINS220 | c.2387C>T p.S796L | Missense Mutation (SNP) | VAF 69/141 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV56760303; called by muse, mutect2, varscan2
- KIF15 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV58164177, COSV58164275; called by muse, mutect2, varscan2
- KIF21B | c.3405C>G p.F1135L | Missense Mutation (SNP) | VAF 25/160 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV59763029; called by muse, mutect2, varscan2
- KIF26A | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100180948, COSV59471123; called by muse, mutect2, varscan2
- KIF5C | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.2); PolyPhen benign (0.035); catalogued as COSV68484227; called by muse, mutect2, varscan2
- KMT2D | c.10855C>T p.L3619F | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.278); catalogued as rs1449620929, COSV99979158; called by muse, mutect2, varscan2
- KMT2D | c.4867G>A p.E1623K | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.566); catalogued as rs754087735, COSV56493449; called by muse, mutect2, varscan2
- KPNB1 | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51600470, COSV51601184; called by muse, mutect2, varscan2
- LAIR2 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 85/344 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as rs770049769, COSV56623232; called by muse, mutect2, varscan2
- LAMA3 | c.2706C>G p.F902L | Missense Mutation (SNP) | VAF 7/193 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1436393256, COSV58082962; called by muse, mutect2
- LAMA3 | c.3966G>A p.M1322I | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as COSV58082973; called by muse, mutect2, varscan2
- LARP1 | c.2393C>T p.S798L (on ENST00000518297 / NM_033551.3; = p.S721L on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV60432093; called by muse, mutect2, varscan2
- LBHD1 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 14/72 reads (19%) | catalogued as COSV100649051; called by muse, mutect2, varscan2
- LCMT1 | c.229del p.V77Sfs*5 | Frame Shift Del (DEL) | VAF 13/61 reads (21%) | catalogued as COSV66727677; called by mutect2, pindel, varscan2
- LCMT2 | c.1277C>T p.S426L | Missense Mutation (SNP) | VAF 56/100 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV59792021; called by muse, mutect2, varscan2
- LCT | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 71/105 reads (68%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs752290809, COSV51470013; called by muse, mutect2, varscan2
- LEMD1 | c.441G>C p.W147C (on ENST00000367151; = p.G100A on NM_001001552.5) | Missense Mutation (SNP) | VAF 34/193 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.187); catalogued as COSV65672243; called by muse, mutect2, varscan2
- LGALS3 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs755491373, COSV54306621; called by muse, mutect2, varscan2
- LHX9 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT tolerated (0.69); PolyPhen benign (0.047); catalogued as rs747939801, COSV61330444, COSV61330587; called by muse, mutect2, varscan2
- LIMD1 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.06); catalogued as COSV56270847; called by muse, mutect2, varscan2
- LIN7B | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as COSV55522546; called by muse, mutect2, varscan2
- LIPE | c.2798G>A p.R933K | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.01); catalogued as rs1445053144, COSV54926076; called by muse, mutect2, varscan2
- LMCD1 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.87); PolyPhen benign (0.084); catalogued as COSV50092779; called by muse, mutect2, varscan2
- LMF2 | c.1559C>G p.P520R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53319553; called by muse, mutect2, varscan2
- LPA | c.5972G>C p.G1991A | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV60314404; called by muse, mutect2, varscan2
- LRP1B | c.11623G>C p.E3875Q | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT tolerated (0.46); PolyPhen benign (0.412); catalogued as COSV67199725, COSV67282558; called by muse, mutect2, varscan2
- LRP4 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV66139162; called by muse, mutect2, varscan2
- LRPPRC | c.306G>C p.K102N | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs772136452, COSV104393446, COSV53244128; called by muse, mutect2, varscan2
- LRRFIP2 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.422); catalogued as COSV60871040; called by muse, mutect2, varscan2
- MAP2K2 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267607230, CM071854, CM101871, COSV53567689, COSV53569132; called by muse, mutect2, varscan2
- MAP2K5 | c.785G>A p.R262K | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.111); catalogued as rs139491783; called by muse, mutect2, varscan2
- MARK1 | c.124C>T p.R42W | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs755425979, COSV65072027; called by muse, mutect2, varscan2
- MAZ | c.600G>C p.K200N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV50719652; called by muse, mutect2, varscan2
- MBD3 | c.309G>C p.Q103H | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV50083998; called by muse, mutect2, varscan2
- MBTPS2 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 44/65 reads (68%) | SIFT tolerated (0.33); PolyPhen benign (0.125); catalogued as rs5951639, COSV63410614, COSV63411558; called by muse, mutect2, varscan2
- MDN1 | c.13167G>C p.E4389D | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.24); PolyPhen benign (0.212); catalogued as COSV65521101, COSV65531845; called by muse, mutect2, varscan2
- MED13L | c.3694C>T p.Q1232* | Nonsense Mutation (SNP) | VAF 30/125 reads (24%) | catalogued as COSV56116552, COSV99928318; called by muse, mutect2, varscan2
- MEI1 | c.3167C>T p.S1056L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as rs745507394, COSV100300122, COSV55905477; called by muse, mutect2, varscan2
- MEI1 | c.3218C>G p.S1073C | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55908721; called by muse, mutect2, varscan2
- MESP2 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.531); catalogued as COSV59093855; called by muse, mutect2, varscan2
- METTL18 | c.878C>T p.S293L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53683488; called by muse, mutect2, varscan2
- METTL23 | c.283G>C p.D95H | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57976347; called by muse, mutect2, varscan2
- METTL2A | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as COSV100274156; called by muse, mutect2, varscan2
- METTL2B | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); catalogued as COSV99299742; called by muse, mutect2, varscan2
- METTL3 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52968467; called by muse, mutect2, varscan2
- METTL3 | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 34/91 reads (37%) | catalogued as COSV99398112; called by muse, mutect2, varscan2
- MEX3D | c.563C>G p.S188C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66312605; called by muse, mutect2, varscan2
- MFAP3 | c.220C>T p.L74F | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs780057486, COSV59457976; called by muse, mutect2, varscan2
- MICAL2 | c.1130C>T p.S377L | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56327454; called by muse, mutect2, varscan2
- MIER1 | c.956C>T p.S319L (on ENST00000355356 / NM_001077701.3; = p.S336L on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62532672; called by muse, mutect2, varscan2
- MIER3 | c.1388C>T p.S463L (on ENST00000381199 / NM_001297599.2; = p.S462L on NM_152622.4) | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as rs201737935, COSV67083411; called by muse, mutect2, varscan2
- MIER3 | c.595G>C p.V199L | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV61229544, COSV61230159; called by muse, mutect2, varscan2
- MINDY1 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.177); catalogued as COSV56498630, COSV56501446; called by muse, mutect2, varscan2
- MMP25 | c.662-1G>A p.X221_splice | Splice Site (SNP) | VAF 41/96 reads (43%) | catalogued as COSV60681650; called by muse, mutect2, varscan2
- MMP26 | c.493G>C p.D165H | Missense Mutation (SNP) | VAF 92/298 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56174306; called by muse, mutect2, varscan2
- MOGS | c.1648C>T p.Q550* | Nonsense Mutation (SNP) | VAF 35/178 reads (20%) | catalogued as COSV51970594, COSV99270393; called by muse, mutect2, varscan2
- MON2 | c.2116C>T p.Q706* | Nonsense Mutation (SNP) | VAF 30/90 reads (33%) | catalogued as COSV99742077; called by muse, mutect2, varscan2
- MORC2 | c.1353G>C p.W451C (on ENST00000397641 / NM_001303256.3; = p.W389C on NM_014941.3) | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); catalogued as COSV53203411; called by muse, mutect2, varscan2
- MOSPD2 | c.1539C>G p.F513L | Missense Mutation (SNP) | VAF 70/103 reads (68%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as COSV66861010; called by muse, mutect2, varscan2
- MPEG1 | c.1808G>A p.S603N | Missense Mutation (SNP) | VAF 53/239 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.052); catalogued as COSV57096264; called by muse, mutect2, varscan2
- MRPS28 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.086); catalogued as rs967487735, COSV52562791, COSV52566114; called by muse, mutect2, varscan2
- MTMR1 | c.1351C>G p.L451V | Missense Mutation (SNP) | VAF 52/76 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV64893093; called by muse, mutect2, varscan2
- MTOR | c.6721C>T p.P2241S | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.674); catalogued as COSV63879321; called by muse, mutect2, varscan2
- MUC16 | c.28787C>T p.S9596L | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.047); catalogued as COSV67500074; called by muse, mutect2, varscan2
- MYH11 | c.3824G>C p.R1275P | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV55572783; called by muse, mutect2, varscan2
- MYH6 | c.4882G>C p.E1628Q | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV62455302; called by muse, mutect2, varscan2
- MYH9 | c.4347C>T p.L1449= | Splice Region (SNP) | VAF 6/20 reads (30%) | catalogued as COSV53394389; called by muse, mutect2
- MYLK | c.5533G>C p.D1845H | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100658751; called by muse, mutect2
- MYOM3 | c.2089C>G p.L697V | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.176); catalogued as COSV100293349, COSV58402120; called by muse, mutect2, varscan2
- MYPN | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.353); catalogued as rs1301769596, COSV62740920; called by muse, mutect2, varscan2
- NAP1L3 | c.1387G>C p.D463H | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.942); catalogued as COSV59076384; called by muse, mutect2, varscan2
- NBEAL2 | c.939G>A p.M313I | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99435288; called by muse, mutect2
- NCAM1 | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV100377279; called by muse, mutect2
- NCOA5 | c.339G>A p.M113I | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV51647925; called by muse, mutect2, varscan2
- NCOR1 | c.7286C>T p.S2429L | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.991); catalogued as COSV51999886; called by muse, mutect2, varscan2
- NCOR1 | c.2227T>G p.S743A | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV51999906; called by muse, mutect2
- NDUFA1 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 91/127 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV65098035; called by muse, mutect2, varscan2
- NDUFB6 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as rs974033134, COSV63083892; called by muse, mutect2, varscan2
- NEBL | c.2642C>G p.S881C | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.662); catalogued as COSV65806394; called by muse, mutect2, varscan2
- NEFM | c.2701G>C p.E901Q | Missense Mutation (SNP) | VAF 62/218 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV55335421; called by muse, mutect2, varscan2
- NEO1 | c.832C>G p.P278A | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56079181; called by muse, mutect2, varscan2
- NFAT5 | c.3546C>G p.F1182L | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1465853159, COSV63026651, COSV63033626; called by muse, mutect2, varscan2
- NFATC2 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV65361999; called by muse, mutect2, varscan2
- NFE2L1 | c.1757C>T p.S586L | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.075); catalogued as COSV62583867; called by muse, mutect2, varscan2
- NFE2L3 | c.1252G>T p.D418Y | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV50242102; called by muse, mutect2, varscan2
- NFIB | c.877C>G p.P293A | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as rs1563833243, COSV66628198; called by muse, mutect2, varscan2
- NGLY1 | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54992192; called by muse, mutect2, varscan2
- NHLRC1 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV61481930; called by muse, mutect2, varscan2
- NLRP14 | c.1064C>G p.S355* | Nonsense Mutation (SNP) | VAF 29/136 reads (21%) | catalogued as COSV100204780; called by muse, mutect2, varscan2
- NLRP7 | c.1669C>T p.L557F | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.563); catalogued as COSV60183093; called by muse, mutect2, varscan2
- NMI | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 31/44 reads (70%) | catalogued as rs146399920; called by muse, mutect2, varscan2
- NOL9 | c.783G>C p.L261F | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV66627149; called by muse, mutect2, varscan2
- NR1I2 | c.267G>C p.K89N | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.79); PolyPhen benign (0.31); catalogued as rs756712963, COSV61978377, COSV61979921; called by muse, mutect2, varscan2
- NR3C1 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 71/177 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.65); catalogued as rs764178904, COSV51547099; called by muse, mutect2, varscan2
- NRXN3 | c.686C>G p.S229C (on ENST00000557594 / NM_001272020.2; = p.S861C on NM_004796.6) | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55361269; called by muse, mutect2, varscan2
- NSRP1 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV55935923; called by muse, mutect2, varscan2
- NSUN7 | c.1294C>T p.Q432* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as rs775660234, COSV100349011; called by muse, mutect2, varscan2
- NT5DC2 | c.1285G>C p.E429Q | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as rs1398511641, COSV58738559, COSV58744029; called by muse, mutect2, varscan2
- NTHL1 | c.759G>T p.K253N (on ENST00000219066; = p.K245N on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/195 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV54594601; called by muse, mutect2, varscan2
- NUDT5 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV66718486; called by muse, mutect2, varscan2
- NUF2 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.458); catalogued as COSV54848006; called by muse, mutect2
- NUP153 | c.3440C>T p.S1147L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV50470285, COSV99029935; called by muse, mutect2, varscan2
- NUP160 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV65856441; called by muse, mutect2, varscan2
- NUP42 | c.1204C>T p.Q402* | Nonsense Mutation (SNP) | VAF 16/107 reads (15%) | catalogued as COSV99330945; called by muse, mutect2, varscan2
- NUP50 | c.794G>T p.G265V | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV61661691; called by muse, varscan2
- NUP50 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.448); catalogued as COSV100754290; called by muse, varscan2
- OAZ1 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV59233781, COSV99077198; called by muse, mutect2, varscan2
- OCRL | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 55/84 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs771573703, COSV63982172; called by muse, mutect2, varscan2
- OMA1 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV62257172; called by muse, mutect2, varscan2
- OR11H1 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as COSV99421708, COSV99421741; called by muse, mutect2, varscan2
- OR13C3 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as rs1201798149, COSV66166422; called by muse, mutect2, varscan2
- OR13C5 | c.807T>G p.N269K | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.102); catalogued as COSV66165446; called by muse, mutect2, varscan2
- OR13D1 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as COSV59515238; called by muse, mutect2, varscan2
- OR2G3 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as rs753400722, COSV60682346, COSV60682414; called by muse, mutect2, varscan2
- OR2L2 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV63562789; called by muse, mutect2, varscan2
- OR52L1 | c.281C>G p.S94C | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV59989700; called by muse, mutect2, varscan2
- OR7G2 | c.741G>C p.L247F | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.315); catalogued as COSV100560589, COSV59689296; called by muse, mutect2, varscan2
- OR8K3 | c.135G>C p.M45I | Missense Mutation (SNP) | VAF 44/176 reads (25%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.007); catalogued as COSV57131709, COSV57133407; called by muse, mutect2, varscan2
- ORC6 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as COSV54478943; called by muse, varscan2
- OSM | c.545C>T p.S182L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs201044676, COSV53161957; called by muse, mutect2, varscan2
- PALM | c.26C>T p.T9M | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.386); catalogued as rs760993265, COSV52766374; called by muse, mutect2, varscan2
- PAQR8 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 31/103 reads (30%) | catalogued as COSV100658419; called by muse, mutect2, varscan2
- PARD3 | c.3343C>T p.Q1115* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as COSV100631443; called by muse, mutect2, varscan2
- PARP1 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 16/88 reads (18%) | catalogued as COSV100828509; called by muse, mutect2, varscan2
- PARVB | c.138G>C p.K46N | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.174); catalogued as COSV58692087; called by muse, mutect2, varscan2
- PCBP1 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 91/216 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as COSV57852211; called by muse, mutect2, varscan2
- PCDHAC2 | c.761C>G p.S254C | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV53874006, COSV53875589; called by muse, mutect2, varscan2
- PCDHGB6 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.021); catalogued as COSV54050074; called by muse, mutect2, varscan2
- PCGF1 | c.203G>A p.C68Y | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52044814; called by muse, mutect2, varscan2
- PCM1 | c.3481G>A p.E1161K | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.43); catalogued as COSV59589221; called by muse, mutect2, varscan2
- PCNT | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 135/217 reads (62%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.775); catalogued as rs1291503523, COSV64025049, COSV64025882, COSV64029451; called by muse, mutect2, varscan2
- PCNT | c.8733G>C p.Q2911H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.753); catalogued as COSV64030285; called by muse, mutect2
- PCSK7 | c.2260G>C p.E754Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.005); catalogued as COSV99638982; called by muse, mutect2, varscan2
- PDE1B | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.69); PolyPhen benign (0.084); catalogued as COSV54497020; called by muse, mutect2, varscan2
- PEG3 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 36/176 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV55650431; called by muse, mutect2, varscan2
- PEX3 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 52/319 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.924); catalogued as COSV52795657; called by muse, mutect2, varscan2
- PFKL | c.917C>T p.S306F | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62465876; called by muse, mutect2, varscan2
- PFKP | c.1908C>T p.L636= | Splice Region (SNP) | VAF 39/133 reads (29%) | catalogued as COSV66891867; called by muse, mutect2, varscan2
- PHB2 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 83/223 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs782318204, COSV54644142; called by muse, mutect2, varscan2
- PHF10 | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59324750; called by muse, mutect2, varscan2
- PHF14 | c.2467C>T p.P823S | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.156); catalogued as COSV68857683; called by muse, mutect2, varscan2
- PHLPP1 | c.4734G>T p.E1578D | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV53040714; called by muse, mutect2, varscan2
- PHLPP2 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as rs762882143, COSV62423892; called by muse, mutect2, varscan2
- PIK3C2A | c.3775C>T p.R1259* | Nonsense Mutation (SNP) | VAF 21/72 reads (29%) | catalogued as rs751934889, COSV99790442; called by muse, mutect2, varscan2
- PIK3C2A | c.2608G>A p.D870N | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.658); catalogued as COSV56407794; called by muse, mutect2, varscan2
- PIK3R4 | c.2180C>T p.S727F | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.584); catalogued as COSV63244415; called by muse, mutect2, varscan2
- PIKFYVE | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1323873660, COSV52250247; called by muse, mutect2, varscan2
- PLAAT5 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.19); catalogued as COSV57138685; called by muse, varscan2
- PLCD4 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.811); catalogued as COSV101346848; called by muse, mutect2
- PLCH1 | c.3149C>G p.S1050* (on ENST00000340059 / NM_001130960.2; = p.S1042* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 40/107 reads (37%) | catalogued as COSV100396111; called by muse, mutect2, varscan2
- PLEKHA6 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99691384; called by muse, mutect2
- PLEKHH2 | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV56762158; called by muse, mutect2, varscan2
- PLEKHH2 | c.2608G>C p.D870H | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56762164; called by muse, mutect2, varscan2
- PLVAP | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 38/136 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53088138; called by muse, mutect2, varscan2
- PLXNB1 | c.1913C>T p.S638F | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.853); catalogued as COSV56494879; called by muse, mutect2, varscan2
- PMM2 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs763091085, COSV51634916; called by muse, mutect2, varscan2
- PMS2 | c.20C>T p.S7L | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.01); catalogued as rs587780048, COSV56149966; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNPLA7 | c.3079G>A p.E1027K | Missense Mutation (SNP) | VAF 70/226 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as rs761498358, COSV53008224, COSV99480022; called by muse, mutect2, varscan2
- PNPT1 | c.100C>A p.Q34K | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.081); catalogued as COSV53180606; called by muse, mutect2, varscan2
- POC5 | c.1550C>T p.S517L (on ENST00000428202 / NM_001099271.2; = p.S492L on NM_152408.2) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1287859139, COSV66843379; called by muse, mutect2, varscan2
- POGK | c.724C>T p.Q242* | Nonsense Mutation (SNP) | VAF 36/74 reads (49%) | catalogued as COSV100902446; called by muse, mutect2, varscan2
- POLDIP3 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 29/82 reads (35%) | catalogued as COSV99348963; called by muse, mutect2, varscan2
- POLG | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.887); catalogued as COSV51525912; called by muse, mutect2, varscan2
- POLR2A | c.1207C>G p.Q403E | Missense Mutation (SNP) | VAF 59/94 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV59496809; called by muse, mutect2, varscan2
- POLR2B | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.981); catalogued as COSV58903182; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.801G>C p.Q267H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV53456445; called by muse, mutect2, varscan2
- PPCS | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 73/172 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.054); catalogued as rs1364205580, COSV65333748; called by muse, mutect2, varscan2
- PPFIA3 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61951924, COSV61955098; called by muse, mutect2, varscan2
- PPIB | c.283C>G p.R95G | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55519980, COSV55521585; called by muse, mutect2, varscan2
- PPM1G | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1408317242, COSV59770846, COSV59772349; called by muse, mutect2, varscan2
- PPP1R3A | c.2566C>G p.Q856E | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV52887278, COSV52887524, COSV52894554; called by muse, mutect2, varscan2
- PPP2R5B | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 64/144 reads (44%) | catalogued as COSV51209701, COSV99375978; called by muse, mutect2, varscan2
- PRG4 | c.2818G>C p.E940Q | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.221); catalogued as COSV63356622; called by muse, mutect2, varscan2
- PRKCD | c.699C>G p.F233L | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57852367; called by muse, mutect2, varscan2
- PRRC1 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 95/232 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.545); catalogued as COSV56991276, COSV56992583; called by muse, mutect2, varscan2
- PRRC2A | c.3317C>T p.S1106L | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV65689361; called by muse, mutect2, varscan2
- PSMC6 | c.562G>A p.G188R (on ENST00000612399; = p.G174R on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV71629455; called by muse, mutect2, varscan2
- PTH2R | c.253C>G p.P85A | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.143); catalogued as COSV55921032; called by muse, mutect2, varscan2
- PTPN3 | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as rs752077556, COSV52711837; called by muse, mutect2, varscan2
- PTPN9 | c.499C>T p.L167F | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60726353; called by muse, mutect2, varscan2
- PTPRM | c.3835C>T p.H1279Y | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs776926312, COSV59869147; called by muse, mutect2, varscan2
- PUM1 | c.256C>T p.Q86* | Nonsense Mutation (SNP) | VAF 47/124 reads (38%) | catalogued as COSV99927486; called by muse, mutect2, varscan2
- RAD21 | c.727G>C p.D243H | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV52064784; called by muse, mutect2, varscan2
- RAD23B | c.1201C>T p.L401F | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63660738; called by muse, mutect2, varscan2
- RAD9B | c.1157C>T p.S386F | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.72); PolyPhen probably damaging (0.967); catalogued as COSV62827474; called by muse, mutect2, varscan2
- RALGAPB | c.2755C>T p.P919S | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as COSV53445545; called by muse, mutect2, varscan2
- RALGPS2 | c.1585G>A p.D529N | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0.057); catalogued as COSV62679510; called by muse, mutect2, varscan2
- RANBP1 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 22/68 reads (32%) | catalogued as COSV99349874; called by muse, mutect2, varscan2
- RARG | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 30/92 reads (33%) | catalogued as COSV100553337; called by muse, mutect2, varscan2
- RASEF | c.353C>T p.S118L | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV61550876; called by muse, mutect2, varscan2
- RASGRF1 | c.3478G>A p.D1160N | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV60213484; called by muse, varscan2
- RASGRF2 | c.979G>C p.D327H | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV104370488, COSV54141321; called by muse, mutect2, varscan2
- RBBP8 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV59096524; called by muse, mutect2, varscan2
- RBM15 | c.2761C>T p.H921Y | Missense Mutation (SNP) | VAF 46/96 reads (48%) | SIFT tolerated (0.92); PolyPhen benign (0.294); catalogued as COSV63924649; called by muse, mutect2, varscan2
- RBM48 | c.82C>T p.R28* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as COSV99720117; called by muse, mutect2, varscan2
- RELN | c.7571G>A p.R2524Q | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs777611799, COSV58985829; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RHOT1 | c.1436C>T p.S479L | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs368654873, COSV100447587; called by muse, mutect2
- RIN1 | c.1777G>A p.G593S | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV60929166; called by muse, mutect2, varscan2
- RIN1 | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV100254425, COSV60929181; called by muse, mutect2, varscan2
- RND3 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as rs1474730686, COSV55726294; called by muse, mutect2, varscan2
- RNF14 | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as COSV100641138; called by muse, mutect2, varscan2
- RNF31 | c.2452C>T p.P818S | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV60728533; called by muse, mutect2, varscan2
- ROBO2 | c.3841C>T p.Q1281* | Nonsense Mutation (SNP) | VAF 41/123 reads (33%) | catalogued as COSV100165372; called by muse, mutect2, varscan2
- RPF1 | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV101035401; called by muse, mutect2, varscan2
- RPL13 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.052); catalogued as COSV51955453; called by muse, varscan2
- RPL13 | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.258); catalogued as rs763239166, COSV51955457; called by muse, varscan2
- RPL15 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as rs766367909, COSV100323206; called by muse, mutect2, varscan2
- RPL23A | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.219); catalogued as rs770497264, COSV52645393; called by muse, mutect2, varscan2
- RPL24 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as COSV67530226; called by muse, mutect2, varscan2
- RPRD2 | c.1982C>T p.S661L | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); catalogued as COSV64823753; called by muse, mutect2, varscan2
- RPS6KA2 | c.145G>C p.E49Q | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV55832032; called by muse, mutect2, varscan2
- RPS6KC1 | c.596C>T p.S199L | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs766825388, COSV65298233; called by muse, mutect2, varscan2
- RPUSD3 | c.149C>G p.S50C | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.436); catalogued as COSV67579605; called by muse, mutect2, varscan2
- RREB1 | c.1195C>T p.Q399* | Nonsense Mutation (SNP) | VAF 16/57 reads (28%) | catalogued as COSV58562166; called by muse, mutect2, varscan2
- RYR1 | c.11783C>G p.S3928C | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62113231; called by muse, mutect2, varscan2
- SAFB | c.1781C>T p.S594L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52654553; called by muse, mutect2, varscan2
- SARM1 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs1020868292; called by muse, varscan2
- SARM1 | c.905C>A p.S302* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99134954; called by muse, mutect2, varscan2
- SCAF11 | c.2449C>T p.P817S | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as COSV65479522; called by muse, mutect2, varscan2
- SCARB2 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV53670822; called by muse, mutect2, varscan2
- SCARF2 | c.1376C>T p.S459L | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.245); catalogued as COSV56734257; called by muse, mutect2, varscan2
- SCRIB | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.991); catalogued as COSV57594444; called by muse, mutect2, varscan2
- SCUBE2 | c.1904C>T p.S635L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); catalogued as COSV58547335; called by muse, mutect2, varscan2
- SEC24C | c.2509G>A p.D837N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.322); catalogued as COSV59545472; called by muse, varscan2
- SENP3 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.857); catalogued as rs762253310, COSV53438319; called by muse, mutect2, varscan2
- SENP6 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs550102590, COSV59195335; called by muse, mutect2, varscan2
- SEPSECS | c.923A>G p.K308R | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV57208049; called by muse, mutect2, varscan2
- SERF2 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV51052120; called by muse, mutect2, varscan2
- SERPINF1 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 100/165 reads (61%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as COSV54618233; called by muse, mutect2, varscan2
- SESN3 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 89/167 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV53587849; called by muse, mutect2, varscan2
- SETD2 | c.6755C>T p.S2252F | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as COSV100338393, COSV57454351; called by muse, mutect2, varscan2
- SETD2 | c.4999C>T p.Q1667* | Nonsense Mutation (SNP) | VAF 81/243 reads (33%) | catalogued as COSV57437153; called by muse, mutect2, varscan2
- SETX | c.1892C>T p.S631F | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV56396460; called by muse, mutect2, varscan2
- SGCZ | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs772544113, COSV101170775, COSV66033304; called by muse, mutect2
- SGCZ | c.508G>C p.D170H | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.606); catalogued as COSV66026203, COSV66035179; called by muse, mutect2, varscan2
- SH2D3C | c.325G>A p.G109R | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs375857347; called by muse, mutect2, varscan2
- SHBG | c.112-1G>C p.X38_splice | Splice Site (SNP) | VAF 66/97 reads (68%) | catalogued as rs754083080, COSV52648062; called by muse, mutect2, varscan2
- SIAH1 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.067); catalogued as COSV53526954; called by muse, mutect2, varscan2
- SIN3A | c.3444G>C p.K1148N | Missense Mutation (SNP) | VAF 44/191 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.045); catalogued as COSV64584016, COSV64585420; called by muse, mutect2, varscan2
- SLC16A6 | c.74G>A p.W25* | Nonsense Mutation (SNP) | VAF 38/95 reads (40%) | catalogued as COSV100517253; called by muse, mutect2, varscan2
- SLC22A23 | c.1520C>T p.S507L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1197640721, COSV100978166; called by muse, mutect2
- SLC22A25 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1345607188, COSV60599895; called by muse, mutect2, varscan2
- SLC24A1 | c.3037G>A p.D1013N | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV56054561; called by muse, mutect2, varscan2
- SLC30A4 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.438); catalogued as COSV56007788; called by muse, mutect2, varscan2
- SLC3A2 | c.1156C>T p.Q386* | Nonsense Mutation (SNP) | VAF 41/106 reads (39%) | catalogued as rs147281603, COSV58604423; called by muse, mutect2, varscan2
- SLC43A2 | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.405); catalogued as COSV56771903; called by muse, mutect2, varscan2
- SLC44A2 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs748376597, COSV59839415; called by muse, mutect2, varscan2
- SLC44A2 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1274028032, COSV59839431; called by muse, mutect2, varscan2
- SLC44A2 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV59837585, COSV59839448; called by muse, mutect2, varscan2
- SLC7A10 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as COSV53507942; called by muse, mutect2, varscan2
- SLCO1B1 | c.581C>G p.S194C | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57018504; called by muse, mutect2, varscan2
- SLFN5 | c.1694C>T p.S565L | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV55484193; called by muse, mutect2, varscan2
- SMC1B | c.2731G>C p.E911Q | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.098); catalogued as COSV100663098, COSV62530393; called by muse, mutect2
- SNRPA1 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV54258763; called by muse, mutect2, varscan2
- SNX14 | c.30G>T p.Q10H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.062); catalogued as COSV59016926; called by muse, mutect2, varscan2
- SNX7 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as rs757467199, COSV60272709; called by muse, mutect2, varscan2
- SON | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.47); catalogued as COSV51672042; called by muse, mutect2, varscan2
- SON | c.6268G>C p.E2090Q | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.963); catalogued as COSV51672064; called by muse, mutect2, varscan2
- SPAG5 | c.1100C>T p.S367L | Missense Mutation (SNP) | VAF 42/178 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as rs140105765; called by muse, mutect2, varscan2
- SPATA20 | c.994G>C p.E332Q (on ENST00000356488 / NM_001258372.1; = p.E348Q on NM_022827.4) | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50071016; called by muse, mutect2, varscan2
- SPDL1 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 30/82 reads (37%) | catalogued as COSV99517449; called by muse, mutect2
- SPP2 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs200722650, COSV51446920; called by muse, mutect2, varscan2
- SRCAP | c.8641C>T p.P2881S | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV52670272, COSV52676371; called by muse, mutect2, varscan2
- SRRM1 | c.1355C>T p.S452L | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV60481168; called by muse, mutect2, varscan2
- SRRM2 | c.4660C>T p.Q1554* | Nonsense Mutation (SNP) | VAF 21/80 reads (26%) | catalogued as COSV100070500; called by muse, mutect2, varscan2
- SRRM3 | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 42/73 reads (58%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.91); catalogued as COSV58387083, COSV58391597; called by muse, mutect2, varscan2
- SSBP2 | c.151A>T p.N51Y | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV57805525; called by muse, mutect2, varscan2
- SSBP3 | c.1158G>T p.M386I (on ENST00000371320 / NM_145716.4; = p.M366I on NM_018070.5) | Missense Mutation (SNP) | VAF 50/219 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); catalogued as COSV58890508; called by muse, varscan2
- STAB1 | c.7084G>A p.E2362K | Missense Mutation (SNP) | VAF 53/140 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as COSV58744025; called by muse, mutect2, varscan2
- STAMBP | c.688C>T p.P230S | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV59898528; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2932C>G p.L978V | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.191); catalogued as rs1339325871, COSV59139625; called by muse, mutect2, varscan2
- STT3B | c.14C>A p.S5* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV55503994, COSV99854077, COSV99854206; called by muse, mutect2, varscan2
- STYX | c.319G>C p.D107H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV63464099; called by muse, mutect2, varscan2
- SUGP2 | c.3049C>T p.Q1017* | Nonsense Mutation (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100431697; called by muse, mutect2, varscan2
- SUSD6 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61367065; called by muse, mutect2
- SUZ12 | c.661C>T p.Q221* | Nonsense Mutation (SNP) | VAF 27/159 reads (17%) | catalogued as COSV100496799; called by muse, mutect2, varscan2
- SYCP1 | c.2914G>A p.E972K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV65701517; called by muse, mutect2, varscan2
- TACR1 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as rs1011770323, COSV100537951, COSV59486814; called by muse, mutect2, varscan2
- TAOK1 | c.1810C>G p.L604V | Missense Mutation (SNP) | VAF 76/294 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.41); catalogued as COSV55599909; called by muse, mutect2, varscan2
- TAS2R20 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs1022728446, COSV67863376; called by muse, mutect2
- TBC1D15 | c.934C>G p.Q312E | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs746284039, COSV59853657; called by muse, mutect2, varscan2
- TBC1D17 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as rs753384830, COSV99680526; called by muse, varscan2
- TBC1D8B | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.904); catalogued as COSV52184221; called by muse, mutect2, varscan2
- TBRG4 | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs775807388, COSV51832050, COSV51834802; called by muse, mutect2, varscan2
- TC2N | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1384224520, COSV61746482; called by muse, mutect2, varscan2
- TCEA3 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV71532256; called by muse, mutect2, varscan2
- TCF19 | c.206G>A p.W69* | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | catalogued as COSV99462833; called by muse, mutect2, varscan2
- TCF19 | c.207G>A p.W69* | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | catalogued as COSV99462834; called by muse, mutect2, varscan2
- TCF25 | c.1320G>C p.Q440H | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.329); catalogued as COSV54533783; called by muse, mutect2, varscan2
- TCHHL1 | c.1666G>C p.E556Q | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV64285165; called by muse, mutect2, varscan2
- TCIRG1 | c.1602G>C p.K534N | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55837821; called by muse, mutect2, varscan2
- TDP2 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV61968942; called by muse, mutect2, varscan2
- TEX15 | c.1582G>A p.E528K (on ENST00000256246; = p.E911K on NM_001350162.2) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs267601897, COSV56347942; called by muse, mutect2, varscan2
- TFAP4 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99200037; called by muse, mutect2, varscan2
- TFPT | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 99/361 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1336894892, COSV58085286; called by muse, mutect2, varscan2
- THADA | c.2729C>T p.S910F | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1052367886, COSV57686159, COSV57694752; called by muse, mutect2, varscan2
- THEMIS2 | c.764G>A p.W255* | Nonsense Mutation (SNP) | VAF 24/81 reads (30%) | catalogued as COSV100197945, COSV61078207; called by muse, mutect2, varscan2
- TIMM21 | c.391G>C p.E131Q | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50053667; called by muse, mutect2, varscan2
- TJP1 | c.3736C>T p.P1246S | Missense Mutation (SNP) | VAF 37/60 reads (62%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.146); catalogued as rs372074311; called by muse, mutect2, varscan2
- TLCD4 | c.726C>G p.I242M | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV64632024, COSV64633755; called by muse, mutect2, varscan2
- TLK2 | c.364C>A p.R122= | Splice Region (SNP) | VAF 15/54 reads (28%) | catalogued as COSV58299985, COSV58306972; called by muse, mutect2, varscan2
- TLR10 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0.009); catalogued as COSV100457471, COSV58302695; called by muse, mutect2, varscan2
- TMEM108 | c.1625G>A p.R542H | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.236); catalogued as rs761644701, COSV56590180; called by muse, mutect2, varscan2
- TMEM109 | c.387G>C p.Q129H | Missense Mutation (SNP) | VAF 53/135 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV50027808; called by muse, mutect2, varscan2
- TMEM109 | c.670G>C p.E224Q | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV50003867, COSV99134496; called by muse, mutect2
- TMOD3 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs1481222197, COSV57946811; called by muse, mutect2, varscan2
- TMPRSS9 | c.764G>A p.R255Q (on ENST00000648592; = p.R221Q on NM_182973.2) | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs200805747, COSV60232077; called by muse, mutect2, varscan2
- TMTC3 | c.1639G>C p.E547Q | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57126717; called by muse, mutect2, varscan2
- TNIK | c.2693C>T p.S898L | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.254); catalogued as COSV52698806, COSV99455584; called by muse, mutect2, varscan2
- TNIP2 | c.961C>G p.Q321E | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV59570367; called by muse, mutect2, varscan2
- TNNT1 | c.246C>G p.I82M | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52571253, COSV52574014; called by muse, mutect2, varscan2
- TNRC6A | c.2563G>A p.D855N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV59370993; called by muse, mutect2, varscan2
- TNRC6B | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV57305958; called by muse, mutect2
- TOR1AIP2 | c.274C>G p.Q92E | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.136); catalogued as COSV62627402; called by muse, mutect2, varscan2
- TPR | c.6460C>T p.H2154Y | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV66605721; called by muse, mutect2, varscan2
- TPTE | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.065); catalogued as rs1481112615; called by muse, mutect2, varscan2
- TRANK1 | c.6207C>A p.C2069* | Nonsense Mutation (SNP) | VAF 19/64 reads (30%) | catalogued as COSV100082211, COSV57163799; called by muse, mutect2, varscan2
- TRAV13-2 | c.116C>G p.S39C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs369797378; called by muse, mutect2, varscan2
- TRGC1 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 52/161 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1021252535; called by muse, mutect2, varscan2
- TRIM37 | c.2228C>T p.S743L | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.375); catalogued as rs376290597, COSV51882623; called by muse, mutect2, varscan2
- TRIM4 | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV62468648; called by muse, mutect2, varscan2
- TRIM40 | c.601C>A p.Q201K (on ENST00000376724; = p.Q172K on NM_138700.4) | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.037); catalogued as COSV57157986; called by muse, mutect2, varscan2
- TRIM45 | c.276C>G p.I92M | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); catalogued as COSV56715147; called by muse, mutect2, varscan2
- TRIM6 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 79/129 reads (61%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as COSV53479678; called by muse, mutect2, varscan2
- TSEN2 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV53191374; called by muse, mutect2, varscan2
- TSHZ2 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.241); catalogued as COSV61592141; called by muse, mutect2, varscan2
- TSN | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT tolerated (0.75); PolyPhen benign (0.021); catalogued as COSV67605238, COSV67605459; called by muse, mutect2, varscan2
- TSPOAP1 | c.3545C>T p.A1182V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1165561991, COSV52119470; called by muse, mutect2, varscan2
- TSPYL1 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV63994059; called by muse, mutect2, varscan2
- TSSC4 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.068); catalogued as COSV50213803; called by muse, mutect2, varscan2
- TSSK4 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV55305443; called by muse, mutect2, varscan2
- TTC37 | c.3344C>G p.S1115C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763151101, COSV100706479; called by muse, mutect2
- TTC39B | c.1304G>A p.W435* | Nonsense Mutation (SNP) | VAF 20/75 reads (27%) | catalogued as COSV99894688; called by muse, mutect2, varscan2
- TTN | c.59511C>G p.I19837M (on ENST00000591111; = p.I12413M on NM_003319.4) | Missense Mutation (SNP) | VAF 71/112 reads (63%) | PolyPhen possibly damaging (0.773); catalogued as COSV60037665; called by muse, mutect2, varscan2
- TUT4 | c.392C>T p.S131L | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV57120499; called by muse, mutect2, varscan2
- TYRO3 | c.2266G>A p.E756K | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV55481275, COSV55487658; called by muse, mutect2, varscan2
- UBA52 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.3); catalogued as COSV55890688, COSV99723643; called by muse, mutect2, varscan2
- UBE2Q1 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 30/165 reads (18%) | catalogued as COSV99427329; called by muse, mutect2, varscan2
- UBN1 | c.2371C>T p.H791Y | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.219); catalogued as rs1485515104, COSV52166435; called by muse, mutect2, varscan2
- UBR4 | c.10982C>T p.P3661L | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV64401861; called by muse, mutect2, varscan2
- UBTD2 | c.96G>C p.L32F | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV67144162; called by muse, mutect2, varscan2
- UBXN2A | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV58338122; called by muse, mutect2, varscan2
- UBXN8 | c.462G>C p.K154N | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV55665916; called by muse, mutect2, varscan2
- UGT2B15 | c.1588G>C p.D530H | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV57734359, COSV57737228; called by muse, mutect2, varscan2
- UHRF2 | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV52796771; called by muse, mutect2, varscan2
- UNC13B | c.3805C>G p.L1269V | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV65939422; called by muse, mutect2, varscan2
- UNC93A | c.1282G>C p.V428L | Missense Mutation (SNP) | VAF 111/285 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV57811315; called by muse, mutect2, varscan2
- USP16 | c.1895C>T p.S632L | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57628343; called by muse, mutect2, varscan2
- USP21 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs770318696, COSV57089746; called by muse, mutect2, varscan2
- USP29 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs866744685, COSV54239877; called by muse, mutect2, varscan2
- USP31 | c.3350C>T p.S1117L | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs780824875, COSV54858363; called by muse, mutect2, varscan2
- USP34 | c.4255-1G>T p.X1419_splice | Splice Site (SNP) | VAF 16/45 reads (36%) | catalogued as COSV68407885; called by muse, mutect2, varscan2
- USP9X | c.2026C>G p.Q676E | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.395); catalogued as COSV61076324; called by muse, mutect2, varscan2
- UTRN | c.9416C>T p.S3139L | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs1005930011, COSV62304201; called by muse, mutect2, varscan2
- VAMP1 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV56948951; called by muse, varscan2
- VENTX | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT tolerated (0.36); PolyPhen benign (0.024); catalogued as COSV58085510; called by muse, mutect2, varscan2
- VN1R2 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as COSV100447836; called by muse, mutect2
- VPS13B | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62160087; called by muse, mutect2, varscan2
- VPS51 | c.1935G>C p.K645N | Missense Mutation (SNP) | VAF 84/340 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV54207983; called by muse, mutect2, varscan2
- VPS72 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV63168384; called by muse, mutect2, varscan2
- WARS1 | c.459G>C p.K153N | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV59928019; called by muse, varscan2
- WASHC2C | c.1792C>T p.Q598* | Nonsense Mutation (SNP) | VAF 60/177 reads (34%) | catalogued as rs781936549, COSV100313867; called by muse, mutect2, varscan2
- WASHC5 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as COSV59201208; called by muse, mutect2, varscan2
- WDCP | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54594152; called by muse, mutect2, varscan2
- WDFY3 | c.7898C>G p.S2633C | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.222); catalogued as COSV55716032; called by muse, mutect2, varscan2
- WDR24 | c.2752G>A p.E918K (on ENST00000248142; = p.E788K on NM_032259.4) | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1342324158, COSV99555534; called by muse, mutect2
- WDR33 | c.3770G>A p.R1257Q | Missense Mutation (SNP) | VAF 103/180 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.147); catalogued as rs770070256, COSV59246071; called by muse, mutect2, varscan2
- WDR83 | c.86G>T p.R29L | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV54419796; called by muse, mutect2, varscan2
- WNT5A | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52839810; called by muse, mutect2, varscan2
- WTAP | c.1133C>T p.S378F | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.33); catalogued as COSV64330881; called by muse, mutect2, varscan2
- WWP1 | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV55365069; called by muse, mutect2, varscan2
- XPO7 | c.2868G>C p.K956N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV53021319; called by muse, mutect2, varscan2
- XYLB | c.1330C>T p.H444Y | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.047); catalogued as COSV52916425; called by muse, mutect2, varscan2
- YARS2 | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 27/89 reads (30%) | catalogued as COSV100256348; called by muse, mutect2, varscan2
- YME1L1 | c.1711G>C p.E571Q (on ENST00000326799 / NM_139312.3; = p.E514Q on NM_014263.4) | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58761846; called by muse, mutect2, varscan2
- ZBTB33 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 87/117 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58535408; called by muse, mutect2, varscan2
- ZBTB5 | c.1263T>G p.F421L | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV57042087; called by muse, mutect2, varscan2
- ZC3H13 | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs775487349, COSV54463549; called by muse, mutect2, varscan2
- ZFC3H1 | c.3031C>T p.Q1011* | Nonsense Mutation (SNP) | VAF 50/161 reads (31%) | catalogued as COSV101110419; called by muse, mutect2, varscan2
- ZFP36L1 | c.275C>A p.S92* | Nonsense Mutation (SNP) | VAF 22/76 reads (29%) | catalogued as COSV100322563, COSV60545656; called by muse, mutect2, varscan2
- ZFP36L1 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV60547565; called by muse, mutect2, varscan2
- ZHX3 | c.2495G>A p.R832Q | Missense Mutation (SNP) | VAF 49/184 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs200260351; called by muse, mutect2, varscan2
- ZHX3 | c.1153C>G p.Q385E | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as COSV58389399; called by muse, mutect2, varscan2
- ZKSCAN1 | c.1085C>T p.S362F | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as COSV60876002; called by muse, mutect2, varscan2
- ZMIZ1 | c.1880C>T p.S627L | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57905114; called by muse, mutect2, varscan2
- ZNF106 | c.4969C>T p.R1657W | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745440803, COSV55522683; called by muse, mutect2, varscan2
- ZNF117 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as rs1317079115, COSV51425998, COSV51430256; called by muse, mutect2, varscan2
- ZNF136 | c.1331G>T p.G444V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59711971; called by muse, mutect2
- ZNF136 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs775998725, COSV59711981; called by muse, mutect2
- ZNF180 | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55425083; called by muse, mutect2, varscan2
- ZNF195 | c.1772C>T p.S591L (on ENST00000399602 / NM_001130520.3; = p.S519L on NM_007152.5) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV50008885; called by muse, mutect2, varscan2
- ZNF208 | c.830T>G p.I277R | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (1); PolyPhen possibly damaging (0.598); catalogued as rs749789908, COSV68113650; called by muse, mutect2, varscan2
- ZNF22 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 23/65 reads (35%) | catalogued as COSV100026554; called by muse, mutect2, varscan2
- ZNF236 | c.1643C>G p.S548C | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53499719; called by muse, mutect2, varscan2
- ZNF382 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV53093072; called by muse, mutect2, varscan2
- ZNF385C | c.1070G>C p.R357T | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.425); catalogued as COSV56918589; called by muse, mutect2, varscan2
- ZNF394 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs1306098241, COSV58742940; called by muse, mutect2, varscan2
- ZNF500 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as COSV54790348; called by muse, mutect2, varscan2
- ZNF518B | c.3004C>T p.Q1002* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | catalogued as COSV100456629; called by muse, mutect2, varscan2
- ZNF524 | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV55609529; called by muse, varscan2
- ZNF549 | c.1358C>T p.S453L (on ENST00000376233 / NM_001199295.2; = p.S440L on NM_153263.2) | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as COSV104383719, COSV53728119; called by muse, mutect2, varscan2
- ZNF555 | c.131-1G>C p.X44_splice | Splice Site (SNP) | VAF 20/56 reads (36%) | catalogued as COSV62074231; called by muse, mutect2, varscan2
- ZNF560 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 55/185 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.005); catalogued as COSV56872422; called by muse, mutect2, varscan2
- ZNF565 | c.1516C>T p.Q506* (on ENST00000355114; = p.Q466* on NM_152477.5 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as COSV100411840; called by muse, mutect2, varscan2
- ZNF566 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.698); catalogued as rs1453413090, COSV67574935; called by muse, mutect2, varscan2
- ZNF57 | c.1298C>T p.S433L | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.283); catalogued as rs759790743, COSV60984941; called by muse, mutect2, varscan2
- ZNF577 | c.921C>G p.F307L | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.898); catalogued as COSV56814933, COSV56818225; called by muse, mutect2, varscan2
- ZNF583 | c.1372C>A p.H458N | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52405021; called by muse, mutect2, varscan2
- ZNF608 | c.2909C>T p.S970F | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.323); catalogued as rs1228012245, COSV60442065; called by muse, mutect2, varscan2
- ZNF611 | c.1043G>T p.C348F | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60543754; called by muse, mutect2, varscan2
- ZNF638 | c.1703C>T p.S568L | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.395); catalogued as rs748059432, COSV52498432; called by muse, mutect2, varscan2
- ZNF664 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 37/162 reads (23%) | catalogued as COSV100544417; called by muse, mutect2, varscan2
- ZNF681 | c.1666C>T p.H556Y | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV68075034; called by muse, mutect2, varscan2
- ZNF695 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV60587835; called by muse, mutect2, varscan2
- ZNF703 | c.1748C>T p.S583L | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV58999617; called by muse, mutect2, varscan2
- ZNF780B | c.1576G>T p.E526* | Nonsense Mutation (SNP) | VAF 23/92 reads (25%) | catalogued as COSV99665493; called by muse, mutect2, varscan2
- ZNF780B | c.533C>G p.S178* | Nonsense Mutation (SNP) | VAF 24/113 reads (21%) | catalogued as COSV99665497; called by muse, mutect2, varscan2
- ZNF792 | c.1498C>T p.H500Y | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68694604; called by muse, mutect2, varscan2
- ZNF813 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 53/300 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as COSV67178355; called by muse, mutect2, varscan2
- ZPBP2 | c.268G>A p.E90K (on ENST00000348931 / NM_199321.3; = p.E68K on NM_198844.3) | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV62375853; called by muse, varscan2
- ZSWIM8 | c.3292C>T p.P1098S (on ENST00000605216 / NM_001242487.2; = p.P1103S on NM_015037.3) | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as rs373327893; called by muse, mutect2, varscan2
- ZZEF1 | c.1204C>G p.L402V | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.386); catalogued as COSV67560671; called by muse, varscan2
- ANKRD36B | c.2803C>G p.Q935E | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.539); called by mutect2, varscan2
- BCAR1 | c.1200_1209del p.D401Wfs*67 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | called by mutect2, pindel, varscan2
- CACNA1D | c.2962del p.V988Sfs*32 (on ENST00000350061 / NM_001128840.3; = p.V1008Sfs*32 on NM_000720.4) | Frame Shift Del (DEL) | VAF 12/108 reads (11%) | called by mutect2, pindel, varscan2
- DRGX | c.637_638delinsT p.A213Sfs*171 | Frame Shift Del (DEL) | VAF 34/149 reads (23%) | called by pindel, varscan2*
- DUSP14 | c.54G>A p.M18I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- H1-2 | c.152_189del p.S51* | Frame Shift Del (DEL) | VAF 23/164 reads (14%) | called by mutect2, pindel
- HERC1 | c.10550G>A p.G3517E | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAGOHB | c.177_197del p.M59_I65del | In Frame Del (DEL) | VAF 14/45 reads (31%) | called by mutect2, pindel
- MUC2 | c.1498C>T p.Q500* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2
- NDUFS5 | c.127_151delinsCAT p.C43Hfs*9 | Frame Shift Del (DEL) | VAF 22/83 reads (27%) | called by pindel, varscan2*
- NECAP1 | c.422_427delinsT p.Q141Lfs*6 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | called by pindel, varscan2*
- TPTE2 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.931); called by muse, mutect2
- TRAV12-3 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 71/215 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.686); called by muse, varscan2
- TRAV34 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- XRN1 | c.4380_4382delinsTT p.R1464Gfs*6 | Frame Shift Del (DEL) | VAF 21/67 reads (31%) | called by pindel, varscan2*
- ZNF223 | c.1244_1292del p.I415Rfs*39 | Frame Shift Del (DEL) | VAF 32/152 reads (21%) | called by mutect2, pindel
- ZNHIT3 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ABCA7 | c.4209G>C p.L1403= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV54038525; called by muse, mutect2, varscan2
- ABL2 | c.573C>T p.I191= (on ENST00000502732 / NM_007314.4; = p.I176= on NM_005158.5) | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV61013852; called by muse, mutect2, varscan2
- ABLIM3 | c.60C>T p.V20= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV58649626; called by muse, mutect2, varscan2
- ACIN1 | c.1029C>T p.S343= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as COSV52983021; called by muse, mutect2, varscan2
- ACOX3 | c.1578C>T p.L526= | Silent (SNP) | VAF 11/75 reads (15%) | catalogued as COSV62712964; called by muse, mutect2, varscan2
- ACTN4 | c.1149C>T p.I383= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99399952; called by muse, varscan2
- ACTR1A | c.1110C>T p.S370= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as COSV53269680; called by muse, mutect2, varscan2
- AHNAK | c.6753C>T p.F2251= | Silent (SNP) | VAF 176/447 reads (39%) | catalogued as rs771639009, COSV57234190; called by muse, mutect2, varscan2
- AHNAK2 | c.1041G>A p.Q347= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV60933498; called by muse, mutect2, varscan2
- AK3 | c.510C>T p.I170= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as COSV63346885, COSV63347363; called by muse, mutect2, varscan2
- ALG2 | c.468G>A p.R156= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as COSV53061100; called by muse, mutect2, varscan2
- ANKS1A | c.2433C>T p.V811= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as COSV64465152; called by muse, mutect2, varscan2
- ANKS3 | c.789C>T p.V263= | Silent (SNP) | VAF 27/114 reads (24%) | catalogued as COSV58512317; called by muse, mutect2, varscan2
- ANP32A | c.450G>A p.R150= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV51190027; called by muse, varscan2
- ARF6 | c.117G>A p.V39= | Silent (SNP) | VAF 20/90 reads (22%) | catalogued as COSV53598576; called by muse, varscan2
372 further variants in this file (0 protein-altering or splice-affecting, 341 silent, 31 other) are not listed here.
